Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9OA, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9OA-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Lymph nodes, right pelvis, excision: No tumor (0/1).
- B. Lymph nodes, left pelvis, excision: Metastatic carcinoma (1/7).
- C. Bladder neck, posterior, biopsy:
- 1. No tumor.
- 2. Unremarkable fibromuscular connective tissue.
- D. Prostate and seminal vesicles, prostatectomy:
- 1. Prostatic adenocarcinoma, Gleason grade 5+4=9, involving both lobes and both seminal vesicles; see comment.
- 2. Metastatic carcinoma in one lymph node (1/1).
- E. Posterior urethra, biopsy:
- 1. No tumor.
- 2. Unremarkable fibromuscular connective tissue.

COMMENT:

Synoptic Comment for Prostate Tumors

- 1. Type of tumor: Small acinar adenocarcinoma.
- 2. Location of tumor: Left posterior mid gland, slides D9, D10, D11; left anterior mid gland, slides D12, D13; right posterior apex, slide D1; right posterior mid gland, slides D6, D7, D8; right anterior apex, slide D1; right anterior mid gland, slides D3, D4.
- 3. Estimated volume of tumor: 5.7 cubic cm.
- 4. Gleason score: 5+4=9.
- 5. Estimated volume > Gleason pattern 3: 100%.
- 6. Involvement of capsule: Tumor invades capsule at right posterior mid gland, slides D6, D7, D8; left posterior mid gland, slide D11.
- 7. Extraprostatic extension: Present, extensive.

ICD-O-3

Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
7/25/14

[page 2 of 3]
8. Status of excision margins for tumor: No tumor at inked margins. Tumor within 0.1 cm in several foci, particularly in posterior prostate.

Status of excision margins for benign prostate glands: Benign glands present at inked excision margins (left apex, slide D1; right apex, slide D2).

9. Involvement of seminal vesicle: Present, both sites.

10. Perineural infiltration: Present.

11. Prostatic intraepithelial neoplasia (PIN): Present focally.

12. AJCC/UICC stage: pT3bN1MX.

Specimen(s) Received

A: Right pelvic lymph nodes

B: Left pelvic lymph nodes

C: Posterior bladder neck

D: Prostate and seminal vesicles (fresh)

E: Posterior urethra

Clinical History

The patient is a [REDACTED] with a history of prostate cancer by core biopsy, Gleason grade ranging from 4 +4 (8) to 5 +4 (9). The patient undergoes a radical retropubic nerve-sparing prostatectomy with bilateral pelvic lymph node dissection.

Gross Description

The specimen is received in five parts, each labeled with the patient's name and unit number. Parts A-C and E are received in formalin; Part D is received fresh.

Part A, additionally labeled "right pelvic lymph nodes," consists of two soft-to-firm, yellow-tan, fibrofatty tissue fragments measuring 3 x 2 x 1.0 cm in aggregate. A single lymph node candidate is identified, bisected, and submitted in cassette A1. The entire fibrofatty remnant is submitted in cassette A2.

Part B, additionally labeled "left pelvic lymph nodes," consists of multiple segments of soft, irregular, yellow-tan, fibrofatty tissue fragments measuring 6.5 x 4 x 1 cm in aggregate. Multiple lymph node candidates are identified and submitted as follows:

Cassettes B1-B2: One lymph node candidate, bisected.

Cassette B3: One lymph node candidate, bisected.

Cassette B4: Two lymph node candidates, bisected.

Cassette B5: Multiple small lymph node candidates submitted intact.

Part C, additionally labeled "posterior bladder neck," consists of a single irregular, unoriented, off-white/tan tissue fragment measuring 0.7 x 0.7 x 0.4 cm. The entire specimen is submitted in cassette C1.

Part D is received fresh additionally labeled "prostate and seminal vesicle". It consists of a single intact prostate gland with attached seminal vesicle/vas deferens bundles weighing 50.5 grams and measuring 4.3 cm from apex to base, 4.4 cm from medial to lateral and 4.9 cm from anterior to posterior. The exterior of the gland is roughened, red-tan and glistening. Sutures are noted along the anterior midline, closing the dorsal vein complex. The seminal vesicle/vas deferens bundles are soft, whorled, red-tan and without lesion or mass. The right anterior surface of the gland is inked green; the left anterior surface is inked blue; and the posterior surface is inked black. The specimen is bisected perpendicular to the urethral channel, and tissue is banked for research/tissue banking purposes. The two halves of the specimen are subsequently glued together, and the specimen is fixed prior to further sectioning. Following fixation, the bladder margin is removed, and the remainder of the gland is serially sectioned perpendicular to the urethral channel from apex to base into eight serial slices. The serial slices reveal a large, solid, off-white/yellow tumor located centrally along the posterior aspect of the gland, which measures 3.0 cm in greatest dimension and grossly abuts the posterior and prostatic capsule. A small, ovoid, 0.4-cm, periprostatic nodule is noted in the left posterior-lateral aspect of serial slices #7-8. This nodule contains a yellow-tan discoloration, which is suspicious for extracapsular

[page 3 of 3]
tumor. Further dissection reveals gross tumor invading both of the seminal vesicle/vas deferens bundles. The apical and bladder margins, as well as representative sections of the prostate and seminal vesicles, are submitted as follows:

Apical Margin:

Cassette D1: Right apex, 12 o'clock to 6 o'clock, breadloafed and submitted entirely.

Cassette D2: Left apex, 6 o'clock to 12 o'clock, breadloafed and submitted entirely.

Right Anterior Quadrant:

Cassette D3: Serial slice #3.

Cassette D4: Serial slice #5.

Cassette D5: Serial slice #7.

Right Posterior Quadrant:

Cassette D6: Serial slice #3.

Cassette D7: Serial slice #5.

Cassette D8: Serial slice #7.

Left Posterior Quadrant:

Cassette D9: Serial slice #3.

Cassette D10: Serial slice #5.

Cassette D11: Serial slice #7.

Left Anterior Quadrant:

Cassette D12: Serial slice #3.

Cassette D13: Serial slice #5.

Cassette D14: Serial slice #7.

Bladder Margin:

Cassette D15: Right lateral bladder margin.

Cassette D16: Central bladder margin.

Cassette D17: Left lateral bladder margin.

Prostatic/Seminal Vesicle Junction:

Cassette D18: Right seminal vesicle and cross section of vas deferens.

Cassette D19: Left seminal vesicle and cross section of vas deferens.

Part E, additionally labeled "posterior urethra," consists of a single irregular, unoriented, tan-brown tissue fragment measuring 0.6 x 0.4 x 0.3 cm in greatest dimension. The specimen is entirely submitted in cassette E1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out on

Source: NCI Genomic Data Commons file eba955d3-aaf2-4e6f-ac58-db7d980724b9 (TCGA-V1-A9OA.F8BC91E0-7D98-40B2-B99E-570564C3ECD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).